Somatic mutation profile of tumor specimen TCGA-DU-5847-01A (aliquot TCGA-DU-5847-01A-11D-1705-08) from TCGA case TCGA-DU-5847, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 34.5 years (12,606 days).
Specimen TCGA-DU-5847-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f231c7f-7b32-4251-a103-463dddc3c561.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5847-10A (Blood Derived Normal), aliquot TCGA-DU-5847-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1362d97-1876-4332-85f4-4d8fb72c00df

The open-access MAF lists 39 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, Nonsense Mutation 2, Splice Site 2, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 41/120 reads (34%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.955dup p.T319Nfs*6 | Frame Shift Ins (INS) | VAF 49/83 reads (59%) | catalogued as rs786204892, CI075686, COSV64290023; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RB1 | c.1333-2A>G p.X445_splice | Splice Site (SNP) | VAF 10/18 reads (56%) | hotspot (GDC flag); catalogued as rs1555286503, CS030552, COSV57301529, COSV57304999, COSV57326295; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANO9 | c.2137G>A p.A713T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV60385540; called by muse, mutect2, varscan2
- APEX2 | c.1215A>T p.Q405H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV58193669; called by muse, mutect2, varscan2
- C4BPB | c.335T>A p.I112N | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54692835; called by muse, mutect2, varscan2
- CRNN | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs150002541, COSV55124081; called by muse, mutect2, varscan2
- DCAF12L1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV64421734, COSV64422590; called by muse, mutect2, varscan2
- EOLA2 | c.325A>T p.N109Y | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV62207605; called by muse, mutect2, varscan2
- FLG | c.8629C>A p.Q2877K | Missense Mutation (SNP) | VAF 112/521 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV64250950; called by muse, mutect2, varscan2
- GRM6 | c.639G>T p.W213C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51450371; called by muse, mutect2, varscan2
- GRM6 | c.638G>A p.W213* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1193824549, COSV51436303; called by muse, mutect2, varscan2
- HIVEP1 | c.2467G>C p.V823L | Missense Mutation (SNP) | VAF 82/118 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65105438; called by muse, mutect2, varscan2
- IST1 | c.938T>C p.V313A (on ENST00000535424 / NM_001270976.1; = p.L299= on NM_014761.4) | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV58666570; called by muse, mutect2, varscan2
- LGALS9C | c.924G>A p.S308= | Splice Region (SNP) | VAF 10/37 reads (27%) | catalogued as rs779319317, COSV60196810; called by muse, mutect2, varscan2
- MAGEL2 | c.3589G>A p.V1197I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV58569438; called by muse, mutect2, varscan2
- MFSD6 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as rs554501896, COSV55622918; called by muse, mutect2, varscan2
- MYO5A | c.4385G>A p.R1462Q | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV62565268; called by muse, mutect2, varscan2
- NCKAP1L | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV53212983; called by muse, mutect2, varscan2
- OR3A2 | c.601A>T p.T201S | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV68695327; called by muse, mutect2, varscan2
- PCDHB13 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs782629609, COSV53401571; called by muse, mutect2, varscan2
- PRDM13 | c.2055C>G p.D685E | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.277); catalogued as COSV65030780; called by muse, mutect2, varscan2
- PTCHD4 | c.1770T>G p.N590K | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV59798739; called by muse, mutect2, varscan2
- SEC31A | c.2790C>G p.H930Q (on ENST00000355196 / NM_001318120.1; = p.H891Q on NM_016211.4) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV52352512; called by muse, mutect2, varscan2
- SLC16A5 | c.971C>G p.A324G | Missense Mutation (SNP) | VAF 301/840 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV61677120; called by muse, mutect2, varscan2
- SLC25A38 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56195627; called by muse, mutect2, varscan2
- SPTBN4 | c.587+1G>A p.X196_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV58960072; called by muse, mutect2, varscan2
- UCKL1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs747630209, COSV62402709; called by muse, mutect2, varscan2
- ZFP42 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV58819524; called by muse, mutect2, varscan2
- ZNF429 | c.1663C>A p.H555N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61919488; called by muse, mutect2, varscan2
- ACO2 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACSL4 | c.1035G>A p.P345= (on ENST00000340800 / NM_022977.2; = p.P304= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/146 reads (39%) | catalogued as rs1409803653, COSV61614030; called by muse, mutect2, varscan2
- APOB | c.12132G>A p.R4044= | Silent (SNP) | VAF 115/376 reads (31%) | catalogued as COSV51955218; called by muse, mutect2, varscan2
- DSG2 | c.165C>T p.P55= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs780650457, COSV55203532; ClinVar: likely benign; called by muse, mutect2, varscan2
- OPHN1 | c.2064C>A p.A688= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV62781450; called by muse, mutect2, varscan2
- POTEF | c.2319C>T p.H773= | Silent (SNP) | VAF 40/148 reads (27%) | catalogued as rs767909910, COSV100664717, COSV62542338; called by muse, varscan2
- RXFP1 | c.435C>T p.C145= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs367796878; called by muse, mutect2, varscan2
- ZNF536 | c.579C>T p.R193= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV62821165, COSV62836290; called by muse, mutect2, varscan2
- OBSCN | c.11659+3664C>T | Intron (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99485203; called by muse, mutect2
